CPTAC case C3N-00383 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46abfc84-7bf3-46e1-9e95-1ad76553ba9b

Demographics
Sex at birth: female; Race: white; Year of birth: 1955; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 60.9 years (22,259 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 790 days (2.2 years); Progression or recurrence: no; Days to last follow up: 790 days (2.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm (a second GDC size field records 3.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 8; Margin status: Uninvolved.

Follow-up (3 entries)
- Days to follow up: 425 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 790 days (2.2 years); Disease response: Complete Response.
- Days to follow up: 790 days (2.2 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 114 kg; Height: 157 cm; BMI: 46; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (11 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00383-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-00383-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 240 mg.
- Sample C3N-00383-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 280 mg.
- Sample C3N-00383-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 111 days; Initial weight: 320 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00383-24: Section location: Entire uterine cavity; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3N-00383-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 350 mg.
- Sample C3N-00383-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 111 days; Initial weight: 110 mg; Time between excision and freezing: 14 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00383-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 120 mg.
- Sample C3N-00383-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 150 mg.
- Samples C3N-00383-31, C3N-00383-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: OCT; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-00383-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 111 days; Method of sample procurement: Blood Draw.
